Gene-level copy-number profile of tumor specimen TCGA-A2-A1G6-01A from TCGA case TCGA-A2-A1G6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.7 years (18,514 days).
Specimen TCGA-A2-A1G6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e64cdbe2-a5a8-4714-b25f-e27b254e95e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A1G6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/b5d369cd-9d52-45da-af85-d8e5d47b7528

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 59,820.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
